Gene-level copy-number profile of tumor specimen TCGA-56-8305-01A from TCGA case TCGA-56-8305, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 72.4 years (26,428 days).
Specimen TCGA-56-8305-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.d217089c-6efb-4077-bb47-41cd62196855.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-56-8305-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/ba15a565-0fd7-4451-89ca-bb4921d439ea

Most common (modal) total copy number across autosomal genes: 5 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 82; copy number 1: 359; copy number 2: 11,825; copy number 3: 9,816; copy number 4: 12,878; copy number 5: 16,661; copy number 6: 5,569; copy number 7: 2,129; copy number 8: 300; copy number 9: 88; copy number 13: 108.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-56-8305-01A-11D-2292-01): tumor purity 0.41, ploidy 3.52, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 82 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,106,543–23,956,444, 67 genes (broad region; genes not listed).
- chr9:30,388,935–31,645,160, 15 genes: LINC01242, SLC4A1APP1, CDRT15P5, RBMXP2, KRT18P66, KRT18P36, RPS26P2, FTLP4, HSPA8P17, AL354854.1, SLC25A6P2, LINC01243, MTATP6P30, MTCO3P30, HMGB3P23.

Amplified relative to the modal value (total copy number ≥ 11, i.e. more than twice the modal value of 5; autosomes only): 108 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr17:77,086,716–80,477,843, 108 genes, copy number 13 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 359. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
